EXCEPTIONAL_RESPONDERS case ER-ABDX — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/700cf333-bf55-4327-8349-a40d3fcbce33

Demographics
Sex at birth: male; Race: white; Year of birth: 1941; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Pancreas, NOS; Classification of tumor: primary; Age at diagnosis: 67.0 years (24,467 days); Year of diagnosis: 2008; AJCC pathologic stage: Stage IB; Prior malignancy: no; Days to last follow up: 2,285 days (6.3 years); Days to best overall response: 729 days (2.0 years); Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Fluorouracil + Irinotecan + Leucovorin Calcium + Oxaliplatin; Days to treatment start: 671 days (1.8 years); Days to treatment end: 758 days (2.1 years).

Follow-up (1 entry)
- Days to follow up: 2,285 days (6.3 years); Disease response: Stable Disease; Progression or recurrence: Yes; Days to recurrence: 669 days (1.8 years); Days progression-free: 2,285 days (6.3 years).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-ABDX-NT1-A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-ABDX-NT1-A-1-0-S1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample ER-ABDX-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: FFPE.
  Slide ER-ABDX-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 10; Percent normal cells: 10; Percent necrosis: 10; Percent stromal cells: 0; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
